Somatic mutation profile of tumor specimen TCGA-P3-A5Q5-01A (aliquot TCGA-P3-A5Q5-01A-11D-A28R-08) from TCGA case TCGA-P3-A5Q5, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 54.0 years (19,728 days).
Specimen TCGA-P3-A5Q5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4de1e16e-a9e2-486d-b2c2-eed00dd3d18e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A5Q5-10A (Blood Derived Normal), aliquot TCGA-P3-A5Q5-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1d2900d-473b-4900-8839-f233c6fee97d

The open-access MAF lists 295 somatic variants for this specimen: 222 protein-altering or splice-affecting, 72 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 72, Nonsense Mutation 13, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSL | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as rs1131691809, CM137018, COSV66965013; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553663084, COSV59557791; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 42/146 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD6 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV99916913; called by muse, mutect2
- ACSS1 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100053443; called by muse, mutect2, varscan2
- ACTR5 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.079); catalogued as COSV99709908; called by muse, mutect2, varscan2
- ADAMTS1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV99535901; called by muse, mutect2, varscan2
- ADAMTS20 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101238990; called by mutect2, varscan2
- ADGRA2 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV100177586; called by muse, mutect2, varscan2
- ADGRG4 | c.9193A>C p.S3065R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99794526; called by muse, mutect2, varscan2
- AHNAK | c.7288G>C p.E2430Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as COSV99945865; called by muse, mutect2, varscan2
- AHNAK | c.7033G>C p.E2345Q | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV57217160, COSV57224566; called by muse, mutect2, varscan2
- AKAP4 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100654167; called by muse, mutect2, varscan2
- AKAP9 | c.11573G>C p.R3858T (on ENST00000359028; = p.R3834T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99133621; called by muse, mutect2, varscan2
- ALOX15B | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200138131, COSV101205572; called by muse, mutect2, varscan2
- AMOTL1 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs768220338, COSV100504220; called by muse, mutect2, varscan2
- ANKRD23 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100450342; called by muse, mutect2, varscan2
- AR | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); catalogued as COSV101017548, COSV65953473, COSV65964919; called by muse, mutect2, varscan2
- ARGFX | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100544072, COSV57681552; called by muse, mutect2, varscan2
- ASPSCR1 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV100142350; called by muse, mutect2, varscan2
- ATAD2 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs528861654, COSV99784154; called by muse, mutect2, varscan2
- BOK | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs1297207589, COSV100572197; called by muse, mutect2, varscan2
- BTBD8 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV100730136; called by muse, mutect2, varscan2
- C4BPA | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as COSV100891159; called by muse, mutect2, varscan2
- CACNA1I | c.5668G>A p.E1890K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV100359381; called by muse, mutect2, varscan2
- CCDC89 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1220393185, COSV57033667; called by muse, mutect2, varscan2
- CCNB1IP1 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100738509; called by muse, mutect2, varscan2
- CDH18 | c.309del p.I103Mfs*14 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as COSV99937751; called by mutect2, pindel, varscan2
- CEP126 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV99680680; called by muse, mutect2, varscan2
- CEP164 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV99632658; called by muse, mutect2, varscan2
- CEP192 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1472527648, COSV100380665, COSV58067929; called by muse, mutect2, varscan2
- CGB7 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100655004; called by muse, mutect2
- CNTNAP2 | c.2968G>A p.D990N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs1060503572, COSV62160231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPSF2 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100102594; called by muse, mutect2, varscan2
- CPT2 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99598060; called by muse, mutect2, varscan2
- CSNK2A2 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV52640962; called by muse, mutect2, varscan2
- CTAGE1 | c.1984C>G p.P662A | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV101194455, COSV66943506; called by muse, mutect2, varscan2
- CYP3A43 | c.458G>C p.G153A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV55937981, COSV99732955; called by muse, mutect2, varscan2
- DDX31 | c.2434G>C p.G812R | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99707464; called by muse, mutect2, varscan2
- DEFB114 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.235); catalogued as COSV100435362, COSV59037751; called by muse, mutect2, varscan2
- DESI2 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1360361594, COSV99797870; called by muse, mutect2, varscan2
- DNAH2 | c.3988G>C p.E1330Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.209); catalogued as COSV101209049; called by muse, mutect2, varscan2
- DNAH5 | c.10390G>C p.E3464Q | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV99445753; called by muse, mutect2, varscan2
- DNMT3B | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs1226308460, COSV52416376; called by muse, mutect2, varscan2
- DPPA2 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs759064635, COSV101524802, COSV72117956; called by muse, mutect2, varscan2
- DPYSL4 | c.267C>G p.F89L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58308206; called by muse, mutect2, varscan2
- DSG2 | c.3151C>G p.L1051V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV99852816; called by muse, mutect2, varscan2
- DSN1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143517734, COSV101040974; called by muse, mutect2, varscan2
- DYNC2I1 | c.2178G>C p.L726F | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101337614; called by muse, mutect2, varscan2
- EHD1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1237944390, COSV57733589; called by muse, mutect2, varscan2
- EIF3B | c.1468C>G p.P490A | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100703566; called by muse, mutect2, varscan2
- EML1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV51749552, COSV51750691; called by muse, mutect2, varscan2
- EP300 | c.5062G>C p.D1688H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607546; called by muse, mutect2, varscan2
- ERBB3 | c.3118C>T p.R1040W | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs200017094, COSV57263375; called by muse, mutect2, varscan2
- F13A1 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.844); catalogued as rs529985469, COSV99342352, COSV99343273; called by muse, mutect2, varscan2
- FAM167B | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as rs368102614; called by muse, mutect2, varscan2
- FAM172A | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV101232673; called by muse, mutect2, varscan2
- FAM20A | c.774G>C p.Q258H | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99873212; called by muse, mutect2
- FAM83C | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as rs376562401; called by muse, mutect2, varscan2
- FANCI | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM161710, COSV100167545; called by muse, mutect2, varscan2
- FARS2 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.368); catalogued as COSV99212911; called by muse, mutect2, varscan2
- FCHO2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99821488; called by muse, mutect2, varscan2
- FLNC | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100367679; called by muse, mutect2, varscan2
- FLNC | c.7560C>T p.T2520= | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as rs527921534, COSV100367683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMO1 | c.950C>G p.S317* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as COSV100707702, COSV61445301; called by muse, mutect2, varscan2
- FNBP4 | c.2974G>C p.E992Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV54093323, COSV54093654, COSV99771372; called by muse, mutect2, varscan2
- FRYL | c.5416G>C p.E1806Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV99976003, COSV99976985; called by muse, mutect2, varscan2
- FRZB | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as rs1237451856, COSV54553155; called by muse, mutect2, varscan2
- GAL3ST2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99510760; called by muse, mutect2, varscan2
- GALNT17 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.932); catalogued as COSV100352570; called by muse, mutect2
- GANAB | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100647856; called by muse, mutect2, varscan2
- GRIK2 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766199284, COSV59715018, COSV59719334; called by muse, mutect2, varscan2
- GRK5 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs758430522, COSV100962855; called by muse, mutect2, varscan2
- GRM6 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51442641, COSV99179468; called by muse, mutect2, varscan2
- GRWD1 | c.418C>G p.Q140E | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99474242; called by muse, mutect2, varscan2
- GTPBP8 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV99868238; called by muse, varscan2
- H2BC15 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 81/343 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as COSV57586158; called by muse, mutect2, varscan2
- H4C6 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV100897474; called by muse, mutect2, varscan2
- HAS2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV100391490; called by muse, mutect2, varscan2
- HDAC3 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539439; called by muse, mutect2
- HECW2 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.038); catalogued as COSV99646077; called by muse, mutect2, varscan2
- HIVEP3 | c.5039C>A p.S1680Y | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56019502, COSV99911642; called by muse, mutect2, varscan2
- HIVEP3 | c.4711C>A p.L1571M | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.347); catalogued as COSV99911644; called by muse, mutect2, varscan2
- HIVEP3 | c.2747C>T p.S916L | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56025605; called by muse, mutect2, varscan2
- HIVEP3 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99911647; called by muse, mutect2, varscan2
- HRAS | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV99529599; called by muse, mutect2, varscan2
- HSPG2 | c.9380G>A p.G3127E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101013346; called by muse, mutect2, varscan2
- HTR1B | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.196); catalogued as COSV100885344, COSV64051584; called by muse, mutect2, varscan2
- HUWE1 | c.9274G>A p.E3092K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99470834; called by muse, mutect2, varscan2
- ICAM5 | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.857); catalogued as COSV99703160; called by muse, mutect2
- IL19 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99536223; called by muse, mutect2, varscan2
- IMMT | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54480175, COSV99606070; called by muse, mutect2, varscan2
- IQGAP1 | c.3967C>G p.P1323A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs1369383129, COSV99184876; called by muse, mutect2, varscan2
- ITGAX | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as COSV99191473; called by muse, mutect2, varscan2
- JAG1 | c.2849C>G p.S950C | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV99652496; called by muse, mutect2, varscan2
- JMJD1C | c.4977G>C p.K1659N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100550183; called by muse, mutect2, varscan2
- KATNAL2 | c.1213G>A p.E405K (on ENST00000356157 / NM_001353899.1; = p.E333K on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99796054; called by muse, mutect2, varscan2
- KBTBD7 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as COSV101068045; called by muse, mutect2, varscan2
- KEL | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs1009140606, COSV100786888; called by muse, mutect2, varscan2
- KIDINS220 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV99875093, COSV99876134, COSV99876569; called by muse, varscan2
- KIF21A | c.2450G>C p.R817T (on ENST00000361418 / NM_001378440.1; = p.R804T on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100735330; called by muse, mutect2, varscan2
- KIF4B | c.1666C>A p.Q556K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV101469201, COSV70529146; called by muse, mutect2, varscan2
- KLHL11 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.025); catalogued as COSV100044205; called by muse, mutect2, varscan2
- KRT222 | c.320A>T p.E107V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101229471; called by muse, mutect2, varscan2
- LPAR2 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480417887, COSV99179096; called by muse, mutect2, varscan2
- LRIT3 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.356); catalogued as COSV100015894; called by muse, mutect2, varscan2
- LRRC19 | c.782C>G p.S261* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101195774; called by muse, mutect2
- LRRTM1 | c.1277A>T p.H426L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV99701944; called by muse, mutect2, varscan2
- MARCHF4 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99814107; called by muse, mutect2, varscan2
- MDGA2 | c.2672T>C p.I891T (on ENST00000399232 / NM_001113498.2; = p.I593T on NM_182830.4) | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs756001459, COSV100636487, COSV62098425; called by muse, mutect2, varscan2
- MFSD14A | c.1105G>T p.V369F | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99790634; called by muse, mutect2, varscan2
- MST1R | c.4142C>T p.S1381L | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.381); catalogued as COSV99617890; called by muse, mutect2, varscan2
- MTBP | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.301); catalogued as COSV100011869; called by muse, mutect2, varscan2
- MUC16 | c.30896C>G p.S10299* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | catalogued as COSV101198396; called by muse, mutect2, varscan2
- MYH3 | c.3675C>G p.F1225L | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99877797; called by muse, mutect2, varscan2
- MYH8 | c.3627G>C p.Q1209H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1377164657, COSV101238275, COSV101238374; called by muse, mutect2, varscan2
- MYO15A | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs772104371, COSV99231379; called by muse, mutect2, varscan2
- MYO16 | c.2780C>T p.S927L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV99193590; called by muse, mutect2, varscan2
- NECTIN4 | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100919836; called by muse, varscan2
- NEDD9 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs1331753330, COSV101053375; called by muse, mutect2
- NEK5 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100839146; called by muse, varscan2
- NEK5 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV100839148; called by muse, varscan2
- NOL4 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52344438, COSV52357322; called by muse, mutect2, varscan2
- NPAS2 | c.717+1G>T p.X239_splice | Splice Site (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100175856; called by muse, mutect2, varscan2
- NPM2 | c.257C>G p.S86* | Nonsense Mutation (SNP) | VAF 68/264 reads (26%) | catalogued as COSV99235659; called by muse, mutect2, varscan2
- NRAP | c.3199G>C p.E1067Q (on ENST00000359988 / NM_001322945.2; = p.E1032Q on NM_006175.4) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); catalogued as COSV100748299; called by muse, mutect2, varscan2
- ODF3B | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99329355; called by muse, mutect2, varscan2
- OPRM1 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as COSV100000548, COSV100001231; called by muse, mutect2, varscan2
- OR10A4 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1428083678, COSV101139445, COSV65842472; called by muse, mutect2, varscan2
- OR51B6 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100970752; called by muse, mutect2, varscan2
- OR6F1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs200002263, COSV57468109, COSV57468895; called by muse, mutect2, varscan2
- OR7G3 | c.365G>C p.R122P | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100555607; called by muse, mutect2, varscan2
- PDZD2 | c.6625G>A p.E2209K | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs779171837, COSV56876273; called by muse, mutect2, varscan2
- PDZRN4 | c.1189G>A p.D397N (on ENST00000402685 / NM_001164595.2; = p.D139N on NM_013377.4) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV100113769; called by muse, mutect2, varscan2
- PFN2 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV99525881; called by muse, mutect2, varscan2
- PHACTR3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs145693547; called by mutect2, varscan2
- PIAS2 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100245057; called by muse, mutect2, varscan2
- PLCE1 | c.4451C>G p.S1484W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM066177, COSV53350732, COSV99593752; called by muse, mutect2, varscan2
- PNKP | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs773641701, COSV55587833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2L | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as COSV58990383, COSV58990492; called by muse, mutect2, varscan2
- PORCN | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs782505896, CM109530, COSV58225577; called by muse, mutect2, varscan2
- PPFIA3 | c.3491C>T p.S1164F | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); catalogued as COSV53256627; called by muse, mutect2
- PPFIA3 | c.3493C>T p.P1165S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.115); catalogued as rs764451903, COSV99417591; called by muse, mutect2
- PPIP5K2 | c.595T>C p.Y199H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100383473; called by muse, mutect2
- PPP1R9A | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs73423007; called by muse, mutect2, varscan2
- PRAMEF10 | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as rs1361126257; called by muse, mutect2
- PTPRD | c.3793G>T p.E1265* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | catalogued as COSV100643646, COSV61985730; called by muse, mutect2, varscan2
- PTPRU | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100111846; called by muse, mutect2, varscan2
- RAB31 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs766774600, COSV101444038; called by muse, mutect2, varscan2
- RARG | c.902A>G p.N301S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100553298; called by muse, mutect2, varscan2
- RESF1 | c.1693C>G p.P565A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as rs1332330973, COSV100440131; called by muse, mutect2, varscan2
- REV3L | c.3618G>C p.K1206N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.518); catalogued as rs1185311270, COSV100724933; called by muse, mutect2, varscan2
- RICTOR | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99704448; called by muse, mutect2, varscan2
- RNASE3 | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100484191, COSV58959180; called by muse, mutect2
- RPGRIP1L | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100045918; called by muse, mutect2, varscan2
- RPL22 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as rs754038770, COSV99329601; called by muse, mutect2, varscan2
- RRM1 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV100331241; called by muse, mutect2, varscan2
- RYK | c.1621C>G p.L541V (on ENST00000620660 / NM_001005861.2; = p.L538V on NM_002958.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs770062508, COSV56061712, COSV56062068, COSV99938639; called by muse, mutect2, varscan2
- SAMD7 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100156778, COSV100156885; called by muse, mutect2, varscan2
- SBF2 | c.2776C>G p.L926V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV56298478, COSV99813353; called by muse, mutect2, varscan2
- SDF4 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs1557517777, COSV55420785, COSV99027809; called by muse, varscan2
- SENP7 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs774738588, COSV58610937; called by muse, mutect2, varscan2
- SERTAD2 | c.207G>C p.L69F | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100512119; called by muse, mutect2, varscan2
- SH3D21 | c.1672G>A p.D558N (on ENST00000453908 / NM_001162530.2; = p.D447N on NM_024676.5) | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV99583929; called by muse, mutect2, varscan2
- SH3RF1 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV52924112, COSV99498710; called by muse, mutect2, varscan2
- SH3RF1 | c.394G>C p.G132R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99498711, COSV99499031; called by muse, mutect2, varscan2
- SI | c.3248G>A p.R1083K | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100014289; called by muse, mutect2, varscan2
- SIMC1 | c.2567C>T p.A856V (on ENST00000443967 / NM_001308196.1; = p.A441V on NM_198567.5) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1020590840, COSV53798852; called by muse, mutect2, varscan2
- SIN3A | c.3043G>C p.E1015Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV100845057; called by muse, mutect2, varscan2
- SIX5 | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.346); catalogued as COSV99352788; called by muse, mutect2
- SLC25A44 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100195773; called by muse, mutect2, varscan2
- SLC26A1 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374288131; called by muse, mutect2, varscan2
- SLC2A2 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100049123; called by muse, mutect2, varscan2
- SLC4A8 | c.2865C>G p.F955L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100176514, COSV60647308; called by muse, mutect2, varscan2
- SLIT2 | c.1511T>C p.L504P | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1560504662, COSV56577077, COSV99881474; called by muse, mutect2, varscan2
- SMC3 | c.1099C>G p.Q367E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100699806; called by muse, mutect2
- SNX19 | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV99772845; called by muse, mutect2
- SPATA33 | c.48G>C p.K16N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV99498269; called by muse, mutect2, varscan2
- SPEF2 | c.2425C>G p.H809D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100606452; called by muse, mutect2, varscan2
- SPP2 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV99394442; called by muse, mutect2, varscan2
- SRPK2 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV61963644; called by muse, mutect2, varscan2
- SULT1A2 | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100187045; called by muse, varscan2
- SWT1 | c.1748C>G p.S583C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100833114; called by muse, mutect2, varscan2
- SYNE1 | c.7238-1G>C p.X2413_splice (on ENST00000367255 / NM_182961.4; = p.X2420_splice on NM_033071.3) | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99555128; called by muse, mutect2, varscan2
- TBC1D8B | c.1892A>T p.Q631L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV52181937, COSV99343940; called by muse, mutect2, varscan2
- TCHH | c.4252G>A p.E1418K | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.361); catalogued as COSV100914914; called by muse, mutect2, varscan2
- TCHH | c.4069G>C p.E1357Q | Missense Mutation (SNP) | VAF 64/347 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.886); catalogued as rs779150318, COSV100914915; called by muse, mutect2, varscan2
- TCHH | c.3411G>C p.E1137D | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100914916; called by muse, mutect2, varscan2
- TIE1 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs183910355, COSV65248998; called by muse, mutect2, varscan2
- TMEM155 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100530046; called by muse, mutect2, varscan2
- TMEM169 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV55264584, COSV99824369; called by muse, varscan2
- TMEM169 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV99824371; called by muse, varscan2
- TMEM248 | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100447244; called by muse, mutect2, varscan2
- TNIK | c.2469G>C p.M823I | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99455432; called by muse, mutect2, varscan2
- TP53BP1 | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV99779905; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV100935640; called by muse, mutect2, varscan2
- TRPM5 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as rs780521772, COSV50153310, COSV50157216; called by muse, mutect2, varscan2
- TTN | c.24140G>C p.R8047T (on ENST00000591111; = p.R7120T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | PolyPhen benign (0.144); catalogued as COSV100597280, COSV60140117; called by muse, mutect2, varscan2
- UBR3 | c.5639G>C p.R1880T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.966); catalogued as COSV99773350, COSV99774942; called by muse, mutect2, varscan2
- UFSP2 | c.117G>C p.L39F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99248920; called by muse, mutect2, varscan2
- UNC5B | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs139601435, COSV100100293, COSV58974547; called by muse, mutect2, varscan2
- USF3 | c.6070C>T p.L2024F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324797; called by muse, mutect2, varscan2
- USP31 | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV99564711; called by muse, mutect2, varscan2
- VPS52 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV101460409; called by muse, mutect2, varscan2
- WIZ | c.5665C>G p.P1889A (on ENST00000673675 / NM_001371589.1; = p.P794A on NM_021241.3) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99652735; called by muse, mutect2, varscan2
- XRN1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV99377342, COSV99378206; called by muse, mutect2
- YY1AP1 | c.613G>C p.E205Q (on ENST00000295566 / NM_139118.2; = p.E128Q on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99803526; called by muse, mutect2
- ZBTB21 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1215115542, COSV100176938; called by muse, mutect2, varscan2
- ZDBF2 | c.3011C>G p.S1004C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100984419; called by muse, mutect2, varscan2
- ZDHHC16 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 32/137 reads (23%) | catalogued as rs1400687848, COSV59135298; called by muse, mutect2, varscan2
- ZKSCAN1 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100164116; called by muse, mutect2, varscan2
- ZMIZ1 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1286766475, COSV100565924; called by muse, mutect2, varscan2
- ZNF234 | c.658C>G p.Q220E | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV101468336; called by muse, mutect2, varscan2
- ZNF253 | c.722C>G p.S241* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV100849461; called by muse, mutect2, varscan2
- ZNF331 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.365); catalogued as COSV99466937; called by muse, mutect2, varscan2
- ZNF700 | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); catalogued as COSV99583305; called by muse, mutect2, varscan2
- ZNF750 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 56/116 reads (48%) | catalogued as COSV99489583; called by muse, mutect2, varscan2
- DDX3X | c.540+2_540+3del | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by pindel, varscan2
- FMO2 | c.981dup p.A328Cfs*5 | Frame Shift Ins (INS) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- IGHV3-35 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- MRC1 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2
- STAT1 | c.1583-4_1598del p.X528_splice | Splice Site (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- ABCA6 | c.2073G>C p.L691= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as COSV99445930; called by muse, mutect2, varscan2
- AHNAK2 | c.7467G>A p.K2489= | Silent (SNP) | VAF 64/415 reads (15%) | catalogued as COSV100315932, COSV60930564; called by muse, mutect2, varscan2
- AMBP | c.612G>A p.R204= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99468839; called by mutect2, varscan2
- ANK1 | c.2520G>A p.E840= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs1182546869, COSV99224160; ClinVar: likely benign; called by muse, mutect2, varscan2
- AOC2 | c.1749C>G p.L583= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as rs760025729, COSV99519996; called by muse, mutect2, varscan2
- ARHGAP39 | c.2898G>T p.L966= (on ENST00000276826 / NM_001308208.2; = p.L997= on NM_025251.2) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99430373; called by muse, mutect2, varscan2
- ASAP3 | c.408G>A p.L136= | Silent (SNP) | VAF 74/382 reads (19%) | catalogued as rs1165690974, COSV100369225; called by muse, varscan2
- CCDC114 | c.1695C>G p.L565= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100196427; called by muse, mutect2, varscan2
- CD207 | c.171C>T p.V57= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV101338533; called by muse, mutect2, varscan2
- CDYL | c.198T>C p.I66= (on ENST00000328908 / NM_001368125.1; = p.I12= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100188829; called by muse, mutect2, varscan2
- COL6A2 | c.276G>C p.L92= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100153051; called by muse, mutect2, varscan2
- COL6A6 | c.3375G>C p.L1125= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV100649905, COSV62034296; called by muse, mutect2, varscan2
- CROCC | c.873C>T p.N291= | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as rs144262827; called by muse, mutect2, varscan2
- CXXC1 | c.990G>A p.V330= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99495601; called by muse, mutect2, varscan2
- CYFIP1 | c.543G>A p.V181= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.1107T>G p.S369= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100150543; called by muse, mutect2, varscan2
- DIP2B | c.3834C>T p.C1278= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs955364149, COSV56588444; called by muse, mutect2, varscan2
- DNAJC13 | c.4758G>A p.L1586= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV53459594, COSV99606722; called by muse, mutect2, varscan2
- DPYSL3 | c.792C>T p.I264= | Silent (SNP) | VAF 51/276 reads (18%) | catalogued as COSV100574921; called by muse, mutect2, varscan2
- DUSP6 | c.201G>A p.Q67= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- EFNB3 | c.756G>A p.R252= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV56832803; called by mutect2, varscan2
- EIF3A | c.3540G>A p.E1180= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs1485475216, COSV100974507; called by muse, mutect2, varscan2
- EPB41L3 | c.639C>T p.I213= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs748696187, COSV100548254; called by muse, mutect2, varscan2
- EPB41L5 | c.2201G>A p.*734= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as COSV99758372; called by muse, mutect2, varscan2
- FANCF | c.1101C>T p.L367= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100541776; called by muse, mutect2, varscan2
- FAT1 | c.11988T>C p.Y3996= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs767993888, COSV101499112; called by muse, mutect2, varscan2
- FLNC | c.4734C>A p.I1578= | Silent (SNP) | VAF 10/161 reads (6%) | catalogued as COSV100367681; called by muse, mutect2
- FOXC1 | c.303G>A p.L101= | Silent (SNP) | VAF 31/212 reads (15%) | catalogued as COSV101083229; called by muse, mutect2, varscan2
- GPR156 | c.996C>T p.F332= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as COSV100251160; called by muse, mutect2, varscan2
- GRIK1 | c.2849G>A p.*950= (on ENST00000327783 / NM_001330994.2; = p.*906= on NM_175611.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100582975; called by muse, mutect2, varscan2
- GRK7 | c.1362T>C p.F454= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV99379561; called by muse, mutect2, varscan2
- GSS | c.501C>T p.L167= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs764765388, COSV99404250; called by muse, mutect2, varscan2
- HHATL | c.474C>T p.I158= | Silent (SNP) | VAF 15/206 reads (7%) | catalogued as COSV60041019; called by muse, mutect2
- HIVEP3 | c.5190C>T p.I1730= | Silent (SNP) | VAF 59/384 reads (15%) | catalogued as COSV99911640; called by muse, mutect2, varscan2
- HM13 | c.1008C>G p.A336= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100159318; called by muse, mutect2, varscan2
- HOMER2 | c.141C>T p.I47= | Silent (SNP) | VAF 36/210 reads (17%) | catalogued as rs1314365015, COSV100420204; called by muse, mutect2, varscan2
- IGHE | c.642G>C p.P214= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs781897805; called by muse, mutect2
- ITGAL | c.852C>T p.I284= | Silent (SNP) | VAF 48/229 reads (21%) | catalogued as rs374466898; called by muse, mutect2, varscan2
- MAGEB16 | c.81T>C p.V27= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV101303283; called by muse, mutect2, varscan2
- MAGI2 | c.3453G>A p.E1151= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100833255; called by muse, mutect2, varscan2
- MAP1B | c.3753C>T p.V1251= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV57100938, COSV99701881; called by muse, mutect2, varscan2
- MYH15 | c.3819A>G p.A1273= | Silent (SNP) | VAF 40/171 reads (23%) | catalogued as COSV99842411; called by muse, mutect2, varscan2
- MYO10 | c.462C>A p.L154= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101549846; called by muse, mutect2, varscan2
- MYO9A | c.6564C>T p.L2188= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV61860916; called by muse, mutect2
- NADSYN1 | c.795C>T p.D265= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs370965046; called by muse, mutect2, varscan2
- NGLY1 | c.1269G>A p.L423= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99770146; called by muse, mutect2, varscan2
- NSMCE4A | c.591C>T p.S197= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100940032; called by muse, mutect2, varscan2
- NUDT16L1 | c.426C>T p.L142= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs149968687; called by muse, mutect2
- OSBPL10 | c.771C>T p.H257= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs550750688, COSV101159030; called by muse, mutect2, varscan2
- PDZD2 | c.6408C>T p.V2136= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as rs576489739, COSV56859554; called by muse, mutect2, varscan2
- POLR1A | c.2277C>T p.Y759= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs377139231; called by muse, mutect2, varscan2
- PTDSS1 | c.357C>T p.L119= | Silent (SNP) | VAF 37/182 reads (20%) | catalogued as COSV100428416, COSV100428964, COSV61266264; called by muse, mutect2, varscan2
- QSOX2 | c.1050G>T p.L350= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100699700; called by muse, mutect2, varscan2
- RYR2 | c.4770C>T p.F1590= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs397516536, COSV100768357; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD4B | c.2082C>T p.I694= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs1234169827, COSV99655607; called by muse, mutect2, varscan2
- SCYL3 | c.396G>A p.V132= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100884263; called by muse, mutect2, varscan2
- SDF4 | c.540C>T p.L180= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV99767380; called by muse, varscan2
- SELENOF | c.9G>C p.A3= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV100085786; called by muse, mutect2, varscan2
- SLC46A1 | c.1371G>A p.Q457= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV50229478; called by muse, mutect2, varscan2
- SLC4A10 | c.3294G>C p.L1098= (on ENST00000446997 / NM_001354461.2; = p.L1068= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99762744; called by mutect2, varscan2
- SOWAHA | c.1422C>A p.S474= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV101097638; called by muse, mutect2, varscan2
- SPCS3 | c.72C>T p.F24= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV101543693; called by muse, mutect2, varscan2
- TBC1D8 | c.258C>T p.I86= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100964300; called by muse, mutect2, varscan2
- TNPO2 | c.210C>G p.L70= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV63510159; called by muse, mutect2, varscan2
- TPTE | c.324C>T p.L108= (on ENST00000618007 / NM_199261.4; = p.L90= on NM_199259.4) | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as rs1208942157; called by muse, mutect2, varscan2
- TTN | c.12093C>T p.N4031= (on ENST00000591111; = p.N3985= on NM_003319.4) | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs879161892, COSV100597284, COSV99045801; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBG2 | c.759C>T p.L253= | Silent (SNP) | VAF 58/257 reads (23%) | catalogued as COSV99257343; called by muse, mutect2, varscan2
- USP20 | c.1953G>A p.V651= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100204055; called by muse, mutect2, varscan2
- USP53 | c.2232G>A p.Q744= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56798845; called by muse, mutect2
- VGLL1 | c.201G>C p.V67= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101034560; called by muse, mutect2, varscan2
- ZFP91 | c.1302C>T p.I434= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs746979173, COSV100284340; called by muse, mutect2, varscan2
- ZNF133 | c.1851C>G p.L617= (on ENST00000316358 / NM_001352454.2; = p.L616= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV60366108; called by muse, mutect2
- GABRA3 | c.-26-27698A>G | Intron (SNP) | VAF 11/30 reads (37%) | catalogued as rs1250754220, COSV100942454; called by muse, mutect2, varscan2
